Gene-level copy-number profile of tumor specimen TCGA-G3-A3CJ-01A from TCGA case TCGA-G3-A3CJ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 52.9 years (19,305 days).
Specimen TCGA-G3-A3CJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.bfed05cc-cbaf-433a-9d67-fc68f96941b3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G3-A3CJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f979e74d-8f7e-431c-9ab2-57e0b563fa84

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 3,399; copy number 2: 48,335; copy number 3: 4,376; copy number 4: 3,507; copy number 5: 189; copy number 7: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G3-A3CJ-01A-11D-A20V-01): tumor purity 0.2, ploidy 2.66, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:28,890,395–29,064,764, 1 gene (within-gene range 0–1): HMBOX1.
- chr8:28,949,676–29,056,685, 3 genes: HMBOX1-IT1, RNA5SP260, AC108449.2.
- chr8:29,067,279–29,068,454, 1 gene: AC108449.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 195 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:50,866,747–51,022,990, 1 gene, copy number 7 (within-gene range 4–7): AC004830.2.
- chr7:51,016,212–63,176,019, 194 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,019. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
